Gene-level copy-number profile of tumor specimen TCGA-UY-A9PA-01A from TCGA case TCGA-UY-A9PA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 48.0 years (17,520 days).
Specimen TCGA-UY-A9PA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.5f8ffb12-b48c-4ceb-ba1b-bed7c347d64e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A9PA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f0529f5-aa04-4860-9078-899add245670

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,386; copy number 2: 55,765; copy number 3: 1,650; copy number 4: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A9PA-01A-11D-A38F-01): tumor purity 0.18, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
